Somatic mutation profile of tumor specimen TCGA-57-1993-01A (aliquot TCGA-57-1993-01A-01W-0699-08) from TCGA case TCGA-57-1993, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.1 years (20,498 days).
Specimen TCGA-57-1993-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d31620c9-ac48-4b09-b69c-c919d6500d0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-57-1993-11A (Solid Tissue Normal), aliquot TCGA-57-1993-11A-01W-0700-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da2b77ec-caf0-4888-98b8-c7b0ac7d49ac

The open-access MAF lists 77 somatic variants for this specimen: 54 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 21, Splice Site 4, Nonsense Mutation 4, Frame Shift Del 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 146/211 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTBL2 | c.603C>A p.F201L | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.46); catalogued as COSV70661670; called by muse, mutect2, varscan2
- ACTBL2 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.582); catalogued as COSV70661112, COSV70661677; called by muse, mutect2, varscan2
- AGK | c.185A>C p.K62T | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV100814735, COSV62594342; called by muse, mutect2, varscan2
- AHNAK2 | c.13795C>A p.Q4599K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.62); catalogued as COSV60928194; called by muse, mutect2
- AOC3 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as rs552584884, COSV99520445; called by muse, mutect2
- CDH10 | c.1982G>A p.G661D | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52594559; called by muse, varscan2
- CEP192 | c.4450G>A p.V1484I | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs749362952, COSV100382354, COSV58069669; called by muse, varscan2
- CLUH | c.867C>G p.I289M (on ENST00000435359; = p.I327M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV70929927; called by muse, mutect2, varscan2
- CST7 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 74/542 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.462); catalogued as COSV65196163; called by muse, varscan2
- DNAH1 | c.9509C>T p.T3170M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs759881712, COSV70235070; called by muse, mutect2, varscan2
- DRG2 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147529975; called by mutect2, varscan2
- ELOVL4 | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV100876430; called by muse, varscan2
- ERCC4 | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.536); catalogued as COSV61313751; called by muse, mutect2, varscan2
- FAM167B | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV61110209, COSV61111084; called by muse, mutect2, varscan2
- GJA4 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs750895718, COSV60725312, COSV60725705; called by muse, mutect2, varscan2
- GMEB2 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs558164590, COSV56607580; called by muse, mutect2, varscan2
- HDAC11 | c.489+1G>C p.X163_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as COSV55474426; called by muse, mutect2, varscan2
- HIVEP2 | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 68/381 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1457519574, COSV50047249; called by muse, mutect2, varscan2
- IQUB | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 37/148 reads (25%) | catalogued as COSV61240313, COSV61242279; called by muse, mutect2, varscan2
- LAMB4 | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs892473975, COSV52729184; called by muse, mutect2
- LRRIQ4 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV61618877; called by muse, mutect2
- LTN1 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV63735072; called by muse, mutect2, varscan2
- MYL6 | c.32-2A>G p.X11_splice | Splice Site (SNP) | VAF 565/721 reads (78%) | catalogued as COSV52879605; called by muse, mutect2, varscan2
- NCAPH2 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV52689222; called by muse, mutect2, varscan2
- NLRP11 | c.2172-1G>T p.X724_splice | Splice Site (SNP) | VAF 34/123 reads (28%) | catalogued as COSV64088106, COSV64088604; called by muse, mutect2
- NPFFR2 | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58153631; called by muse, mutect2, varscan2
- NRAP | c.4318G>T p.E1440* (on ENST00000359988 / NM_001322945.2; = p.E1405* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 14/218 reads (6%) | catalogued as COSV100748643; called by muse, mutect2
- NUP133 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1279536324, COSV54574805; called by muse, mutect2, varscan2
- NUP188 | c.2329G>A p.V777I | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV101001347; called by muse, mutect2
- OSBPL6 | c.2386A>G p.K796E | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99508689; called by muse, mutect2
- P4HB | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58941622; called by muse, mutect2, varscan2
- PAFAH2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs200838566, COSV65340139; called by muse, mutect2, varscan2
- PTPN4 | c.2434C>G p.Q812E | Missense Mutation (SNP) | VAF 178/258 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV55307915; called by muse, mutect2, varscan2
- RALGAPA2 | c.4231G>A p.V1411M | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV99175155; called by muse, mutect2, varscan2
- RECQL | c.1416C>A p.N472K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as rs755294309, COSV53711530; called by muse, mutect2, varscan2
- RGL2 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV65842888; called by muse, mutect2, varscan2
- RIMBP2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 31/404 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99900729; called by muse, mutect2
- RTP3 | c.603C>A p.Y201* | Nonsense Mutation (SNP) | VAF 14/174 reads (8%) | catalogued as COSV56123798, COSV99947010; called by muse, mutect2
- SLITRK1 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV65674732, COSV65677259; called by muse, mutect2, varscan2
- SPEN | c.6457G>A p.V2153M | Missense Mutation (SNP) | VAF 97/577 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.475); catalogued as rs761978747, COSV65366819; called by muse, mutect2, varscan2
- SPOCK3 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100694202; called by muse, mutect2, varscan2
- SS18L1 | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as COSV59208743, COSV59209473; called by muse, mutect2, varscan2
- SUN5 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100644928; called by muse, mutect2, varscan2
- UGDH | c.980C>G p.T327S | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100328599; called by muse, varscan2
- WIF1 | c.397+1G>A p.X133_splice | Splice Site (SNP) | VAF 26/156 reads (17%) | catalogued as COSV54135177; called by muse, mutect2, varscan2
- ZMAT3 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 91/682 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV60995064; called by muse, mutect2, varscan2
- ZNF107 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100788549; called by muse, mutect2
- ZNF14 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1387249930, COSV59851096; called by muse, mutect2, varscan2
- ZNF846 | c.1568A>G p.K523R | Missense Mutation (SNP) | VAF 70/551 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV67412568; called by muse, mutect2, varscan2
- NISCH | c.2260del p.L754Sfs*219 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- NUMB | c.1702A>T p.S568C (on ENST00000355058; = p.S557C on NM_003744.5) | Missense Mutation (SNP) | VAF 104/140 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.353); called by mutect2, varscan2
- PWWP2A | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.258); called by muse, varscan2
- SLC9B1 | c.1229del p.C410Lfs*5 | Frame Shift Del (DEL) | VAF 23/99 reads (23%) | called by mutect2, pindel, varscan2
- ACTBL2 | c.849C>T p.I283= | Silent (SNP) | VAF 15/168 reads (9%) | catalogued as COSV101379424; called by muse, mutect2
- AGPS | c.610C>A p.R204= | Silent (SNP) | VAF 22/182 reads (12%) | catalogued as COSV51568402; called by muse, mutect2, varscan2
- ASXL1 | c.243C>T p.F81= | Silent (SNP) | VAF 55/401 reads (14%) | catalogued as COSV60120337; called by muse, mutect2, varscan2
- CFAP69 | c.1461G>A p.L487= | Silent (SNP) | VAF 7/158 reads (4%) | catalogued as COSV100290502, COSV60188951; called by muse, mutect2
- CLVS2 | c.114C>T p.V38= | Silent (SNP) | VAF 30/182 reads (16%) | catalogued as COSV51558502; called by muse, mutect2, varscan2
- FCHSD2 | c.465C>T p.Y155= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100239211, COSV60813977; called by muse, mutect2, varscan2
- GGA2 | c.1596C>A p.I532= | Silent (SNP) | VAF 49/180 reads (27%) | catalogued as rs200357653, COSV59170232; called by muse, mutect2, varscan2
- H1-7 | c.699G>A p.K233= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1317164117, COSV58602886; called by muse, mutect2, varscan2
- HAS2 | c.1585C>T p.L529= | Silent (SNP) | VAF 26/457 reads (6%) | catalogued as COSV100391469, COSV58265340; called by muse, mutect2
- HSPG2 | c.2547C>A p.R849= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV65976594; called by muse, mutect2, varscan2
- MBTD1 | c.1668A>G p.Q556= | Silent (SNP) | VAF 76/168 reads (45%) | catalogued as rs766093480, COSV64503346; called by muse, mutect2, varscan2
- MCM3AP | c.4440G>A p.L1480= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV99387601; called by muse, mutect2
- NPL | c.516G>A p.L172= | Silent (SNP) | VAF 25/193 reads (13%) | catalogued as COSV51127356; called by muse, mutect2, varscan2
- NPRL3 | c.726G>A p.L242= (on ENST00000611875 / NM_001077350.3; = p.L217= on NM_001039476.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV67854435; called by muse, mutect2, varscan2
- PTPN22 | c.2124C>A p.A708= (on ENST00000359785 / NM_001193431.2; = p.A653= on NM_012411.5) | Silent (SNP) | VAF 29/215 reads (13%) | catalogued as rs759532960, COSV100704013; called by muse, mutect2, varscan2
- STYK1 | c.411C>T p.D137= | Silent (SNP) | VAF 30/808 reads (4%) | catalogued as rs1433846911, COSV99311683; called by muse, mutect2
- TAF9B | c.306C>T p.T102= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV100540777, COSV59372088; called by muse, mutect2, varscan2
- TEC | c.1248G>T p.V416= | Silent (SNP) | VAF 18/344 reads (5%) | catalogued as COSV101202696; called by muse, mutect2
- TXNDC2 | c.744G>A p.Q248= (on ENST00000306084 / NM_001098529.2; = p.Q181= on NM_032243.6) | Silent (SNP) | VAF 60/193 reads (31%) | catalogued as COSV60155379; called by muse, mutect2, varscan2
- VWA8 | c.1569G>A p.T523= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as rs772171662, COSV55703706; called by muse, mutect2, varscan2
- ZC3H4 | c.3000G>A p.A1000= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs771839449, COSV53410616; called by muse, mutect2, varscan2
- KIF16B | c.3498+3029G>T | Intron (SNP) | VAF 37/277 reads (13%) | catalogued as COSV100734984; called by muse, mutect2, varscan2
- ZSCAN32 | c.695-134G>A | Intron (SNP) | VAF 9/61 reads (15%) | catalogued as rs756325936, COSV59236976; called by muse, mutect2, varscan2
